Somatic mutation profile of tumor specimen TCGA-AB-2826-03B (aliquot TCGA-AB-2826-03B-01W-0728-08) from TCGA case TCGA-AB-2826, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 64.3 years (23,468 days).
Specimen TCGA-AB-2826-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e9e079d5-9559-4f30-82c7-e7083d6297fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2826-11B (Solid Tissue Normal), aliquot TCGA-AB-2826-11B-01W-0728-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a72689b3-2839-4f09-990a-492ed1c7fded

The open-access MAF lists 654 somatic variants for this specimen: 483 protein-altering or splice-affecting, 159 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 415, Silent 159, Nonsense Mutation 33, Frame Shift Ins 20, Splice Site 8, Intron 7, Frame Shift Del 5, 3'Flank 3, RNA 1, Splice Region 1, 3'UTR 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HARS2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 21/469 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1432653451, COSV51226858; ClinVar: likely pathogenic; called by muse, mutect2
- KMT2D | c.16501C>T p.R5501* | Nonsense Mutation (SNP) | VAF 24/710 reads (3%) | catalogued as rs886041398, CM105482, COSV56407191; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by pindel, varscan2
- ABCB5 | c.3475G>A p.G1159S (on ENST00000404938 / NM_001163941.2; = p.G714S on NM_178559.6) | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs142824450; called by muse, mutect2
- ABCC11 | c.3803A>T p.H1268L | Missense Mutation (SNP) | VAF 45/1369 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100751242; called by muse, mutect2
- ACO1 | c.2462G>T p.G821V | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100008802; called by muse, mutect2, varscan2
- ACO2 | c.290C>G p.A97G | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV99347849; called by muse, mutect2, varscan2
- ACOT11 | c.447C>A p.F149L | Missense Mutation (SNP) | VAF 476/2422 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV100650816, COSV59346499; called by muse, varscan2
- ACSF2 | c.604C>G p.P202A | Missense Mutation (SNP) | VAF 24/323 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.163); catalogued as COSV99366346; called by muse, mutect2
- ACTL8 | c.389C>G p.A130G | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV100958846; called by muse, mutect2, varscan2
- ACVR1B | c.1377G>C p.W459C | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99232166; called by muse, mutect2
- ADGRB3 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 22/646 reads (3%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV101002088; called by muse, mutect2
- ADGRL2 | c.2495C>T p.A832V (on ENST00000370717 / NM_001366005.1; = p.A819V on NM_012302.4) | Missense Mutation (SNP) | VAF 13/130 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV54687508; called by muse, mutect2
- ADRA1A | c.980C>A p.P327Q | Missense Mutation (SNP) | VAF 78/1040 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99372628; called by muse, mutect2
- AHR | c.2506G>A p.A836T | Missense Mutation (SNP) | VAF 52/333 reads (16%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.017); catalogued as COSV99620395; called by muse, varscan2
- AHSA1 | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 21/729 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); catalogued as COSV99376265; called by muse, mutect2
- AIDA | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 18/452 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.966); catalogued as COSV100388486; called by muse, mutect2
- ALCAM | c.1483G>T p.V495L | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV100065975; called by muse, mutect2
- ALK | c.3008A>G p.K1003R | Missense Mutation (SNP) | VAF 32/762 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV101202830; called by muse, mutect2
- AMOT | c.2231T>A p.M744K (on ENST00000371959 / NM_001113490.1; = p.M335K on NM_133265.3) | Missense Mutation (SNP) | VAF 48/978 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100495671; called by muse, mutect2
- ANKRD13C | c.307G>A p.V103I | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV99257930; called by muse, mutect2
- ANKRD50 | c.3349G>A p.E1117K | Missense Mutation (SNP) | VAF 43/259 reads (17%) | SIFT tolerated (0.66); PolyPhen benign (0.168); catalogued as COSV72386297; called by muse, mutect2, varscan2
- ANKS1B | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 2549/2788 reads (91%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1390785746, COSV100246196; called by muse, mutect2, varscan2
- AP1G1 | c.2377C>T p.R793* | Nonsense Mutation (SNP) | VAF 34/284 reads (12%) | catalogued as COSV100251171; called by muse, mutect2, varscan2
- AP1M1 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 24/295 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV99358693; called by muse, mutect2
- APBA2 | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.483); catalogued as rs575379564, COSV101381956; called by muse, mutect2, varscan2
- APC | c.8140C>T p.R2714C | Missense Mutation (SNP) | VAF 31/372 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs864622205, COSV57331764; ClinVar: uncertain significance; called by muse, mutect2
- APOA5 | c.494dup p.V166Rfs*102 | Frame Shift Ins (INS) | VAF 12/98 reads (12%) | catalogued as rs764366547; called by mutect2, pindel
- AR | c.1108G>C p.A370P | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as COSV101019766; called by muse, mutect2
- ARHGEF18 | c.941G>A p.G314D (on ENST00000359920 / NM_001130955.2; = p.G210D on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.281); catalogued as COSV100150156; called by muse, mutect2, varscan2
- ARID1A | c.3701G>A p.G1234D | Missense Mutation (SNP) | VAF 23/444 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100253913; called by muse, mutect2
- ARL11 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs753334860, COSV56292190; called by muse, mutect2, varscan2
- ARNT | c.823G>C p.D275H | Missense Mutation (SNP) | VAF 76/772 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV100591459; called by muse, mutect2
- ARPP19 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 46/488 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV99993013; called by muse, mutect2
- ARPP19 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 31/881 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV99993016; called by muse, mutect2
- ARSL | c.1607A>G p.Q536R | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.045); catalogued as COSV101140821; called by muse, mutect2
- ASGR2 | c.745G>A p.G249S | Missense Mutation (SNP) | VAF 38/952 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99643204; called by muse, mutect2
- ATG13 | c.1354G>C p.A452P (on ENST00000359513 / NM_001346321.1; = p.A415P on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV100366127; called by muse, mutect2
- ATP1A1 | c.3041G>T p.G1014V | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99814873; called by muse, mutect2
- ATP1A2 | c.3035G>A p.G1012D | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100767896, COSV100768224; called by muse, mutect2
- ATP8B4 | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 18/296 reads (6%) | catalogued as COSV52727954; called by muse, mutect2
- B3GALT4 | c.725dup p.R243Qfs*108 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | catalogued as rs779828300; called by pindel, varscan2
- BAX | c.378C>G p.C126W | Missense Mutation (SNP) | VAF 31/784 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); catalogued as COSV99509322; called by muse, mutect2
- BAZ2B | c.3200G>A p.C1067Y | Missense Mutation (SNP) | VAF 25/396 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99681099; called by muse, mutect2
- BCAM | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 14/434 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV99539060; called by muse, mutect2
- BCL9 | c.3451G>A p.V1151I | Missense Mutation (SNP) | VAF 26/636 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV99326041; called by muse, mutect2
- BCORL1 | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 22/474 reads (5%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.005); catalogued as COSV99501265; called by muse, mutect2
- BLZF1 | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 19/497 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV100250884, COSV61394265; called by muse, mutect2
- BMP2K | c.3313C>T p.Q1105* | Nonsense Mutation (SNP) | VAF 32/316 reads (10%) | catalogued as COSV99784852; called by muse, mutect2, varscan2
- BNIP1 | c.398A>G p.Q133R | Missense Mutation (SNP) | VAF 38/890 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV99199483; called by muse, mutect2
- BOD1L1 | c.7237G>A p.V2413I | Missense Mutation (SNP) | VAF 54/506 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99240603; called by muse, mutect2, varscan2
- BPIFB6 | c.1307T>A p.L436Q | Missense Mutation (SNP) | VAF 16/344 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.109); catalogued as COSV100848565; called by muse, mutect2
- BRD4 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99651595; called by muse, mutect2
- BTBD1 | c.1361C>T p.T454I | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.127); catalogued as COSV99915783; called by mutect2, varscan2
- BTBD10 | c.1271C>A p.S424Y | Missense Mutation (SNP) | VAF 34/612 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99534000; called by muse, mutect2
- BTBD7 | c.1220A>T p.K407M | Missense Mutation (SNP) | VAF 30/474 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100598296; called by muse, mutect2
- BTG1 | c.279G>C p.E93D | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.034); catalogued as COSV99755797; called by muse, mutect2, varscan2
- BTN1A1 | c.58C>G p.Q20E | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.146); catalogued as COSV99764613; called by muse, mutect2
- C16orf70 | c.1141G>A p.G381S | Missense Mutation (SNP) | VAF 34/494 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99531693; called by muse, mutect2
- C1S | c.971G>A p.G324E | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1555162300, COSV100196820; called by muse, mutect2
- C1orf162 | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 20/448 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as COSV100636256; called by muse, mutect2
- CACNA1C | c.3047A>G p.K1016R | Missense Mutation (SNP) | VAF 39/528 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100223422; called by muse, mutect2
- CACNA2D3 | c.2207G>A p.R736K | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99878100; called by muse, mutect2
- CAMKK2 | c.700T>C p.Y234H | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV61215026; called by muse, mutect2
- CBLL2 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 15/336 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100081475, COSV100081801; called by muse, mutect2
- CCDC102B | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.148); catalogued as COSV100105259; called by muse, mutect2, varscan2
- CCDC127 | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as rs1183267314, COSV57257982, COSV99723191; called by muse, mutect2
- CD226 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99711632; called by muse, mutect2
- CD5L | c.136G>A p.G46S | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV100941238, COSV63822899; called by muse, mutect2
- CD69 | c.77G>A p.S26N | Missense Mutation (SNP) | VAF 20/428 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV99946224; called by muse, mutect2
- CD72 | c.10G>C p.A4P | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99427674; called by muse, mutect2
- CDC14A | c.1602T>G p.N534K | Missense Mutation (SNP) | VAF 34/319 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.986); catalogued as COSV100326158; called by muse, mutect2
- CDC23 | c.625C>T p.L209F | Missense Mutation (SNP) | VAF 16/492 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101203019; called by muse, mutect2
- CDH1 | c.917G>A p.S306N | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99932817; called by muse, mutect2
- CDH19 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1271572454, COSV100050839; called by muse, mutect2
- CDH23 | c.6832A>G p.K2278E | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99824475; called by muse, mutect2
- CDHR1 | c.2141C>T p.A714V | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.006); catalogued as COSV100259462; called by muse, mutect2
- CELF1 | c.119G>T p.G40V | Missense Mutation (SNP) | VAF 25/552 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV100137287; called by muse, mutect2
- CELSR2 | c.5133dup p.P1712Afs*64 | Frame Shift Ins (INS) | VAF 5/50 reads (10%) | catalogued as rs758744289; called by pindel, varscan2
- CENATAC | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs781975206, COSV100548955; called by mutect2, varscan2
- CENPE | c.2102C>T p.T701I | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99478459; called by muse, mutect2
- CH25H | c.373C>A p.L125M | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.472); catalogued as COSV100897398; called by muse, mutect2
- CHD8 | c.671T>A p.L224* | Nonsense Mutation (SNP) | VAF 8/90 reads (9%) | catalogued as rs1555318576, COSV101303233; called by muse, mutect2
- CHRD | c.1447G>A p.G483S | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99200997; called by muse, mutect2
- CHRNA2 | c.979C>G p.L327V | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV99532600; called by muse, mutect2, varscan2
- CHRNA9 | c.310T>C p.S104P | Missense Mutation (SNP) | VAF 17/416 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.633); catalogued as COSV100039183; called by muse, mutect2
- CHUK | c.1304C>A p.S435Y | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as COSV100957306; called by muse, mutect2, varscan2
- CIT | c.1666-1G>T p.X556_splice | Splice Site (SNP) | VAF 22/307 reads (7%) | catalogued as COSV99951353; called by muse, mutect2
- CLCN2 | c.1967A>T p.Q656L | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV99659108; called by muse, varscan2
- CLPTM1 | c.1612C>A p.H538N | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100494077; called by muse, mutect2
- CNOT10 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs1318581875, COSV100095263; called by muse, mutect2
- CNTD1 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 31/739 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100113657; called by muse, mutect2
- COL18A1 | c.1751T>C p.V584A (on ENST00000359759 / NM_130444.3; = p.V349A on NM_030582.4) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100701008; called by muse, varscan2
- COL2A1 | c.3692A>G p.K1231R | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV100477809; called by muse, varscan2
- CPA1 | c.1192C>A p.P398T | Missense Mutation (SNP) | VAF 50/1187 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99163387; called by muse, mutect2
- CSDE1 | c.1979G>A p.G660D (on ENST00000358528 / NM_001007553.3; = p.G629D on NM_007158.6) | Missense Mutation (SNP) | VAF 29/527 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV54759427, COSV99796277; called by muse, mutect2
- CSF3R | c.1823C>T p.A608V | Missense Mutation (SNP) | VAF 30/564 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.412); catalogued as COSV100118357; called by muse, mutect2
- CSGALNACT1 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 30/486 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100175807; called by muse, mutect2
- CST11 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 20/434 reads (5%) | catalogued as COSV100983590; called by muse, mutect2
- CTSK | c.896G>T p.G299V | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99649045; called by muse, mutect2
- CXCL16 | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 35/355 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as COSV99351931; called by muse, mutect2
- CYTH1 | c.329C>T p.T110I | Missense Mutation (SNP) | VAF 12/195 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as COSV100739554; called by muse, mutect2
- DCLK3 | c.438G>T p.R146S | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV101374179; called by muse, mutect2
- DCUN1D3 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100177111, COSV60954975; called by muse, mutect2
- DDAH2 | c.725T>A p.L242Q | Missense Mutation (SNP) | VAF 42/579 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.762); catalogued as COSV101007572; called by muse, mutect2
- DDX49 | c.368T>C p.V123A | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV99447947; called by muse, mutect2
- DDX50 | c.2176C>T p.R726* | Nonsense Mutation (SNP) | VAF 28/192 reads (15%) | catalogued as rs760232514, COSV65291971; called by muse, mutect2, varscan2
- DECR1 | c.966G>A p.W322* | Nonsense Mutation (SNP) | VAF 30/326 reads (9%) | catalogued as COSV99616643; called by muse, mutect2
- DIXDC1 | c.2032G>A p.E678K (on ENST00000440460 / NM_001037954.4; = p.E467K on NM_033425.4) | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555178116, COSV59462223, COSV59462480; called by muse, mutect2, varscan2
- DNAH3 | c.8990G>A p.G2997D | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99771319; called by muse, mutect2
- DNAH3 | c.2476A>T p.N826Y | Missense Mutation (SNP) | VAF 27/615 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as COSV99771328; called by muse, mutect2
- DNAH7 | c.4267A>T p.T1423S | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.6); catalogued as COSV100418160; called by muse, mutect2, varscan2
- DNAH9 | c.9874G>T p.A3292S | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.859); catalogued as COSV99308807; called by muse, mutect2, varscan2
- DNAJB2 | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV99834462; called by muse, mutect2, varscan2
- DOK4 | c.320T>C p.L107P | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV99538540; called by muse, mutect2
- DPEP3 | c.1303C>G p.H435D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV99262951; called by muse, mutect2, varscan2
- DQX1 | c.1494A>G p.T498= | Splice Region (SNP) | VAF 30/656 reads (5%) | catalogued as COSV101099282; called by muse, mutect2
- DUSP26 | c.98A>G p.E33G | Missense Mutation (SNP) | VAF 112/619 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as COSV99823616; called by muse, mutect2, varscan2
- E2F8 | c.2513G>A p.C838Y | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs866204691, COSV100001829; called by muse, mutect2
- EFTUD2 | c.2506G>A p.V836I | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.085); catalogued as rs1300798893, COSV99494062; called by muse, mutect2
- ENTPD6 | c.1163T>A p.L388H | Missense Mutation (SNP) | VAF 13/252 reads (5%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.962); catalogued as COSV100737204; called by muse, mutect2
- EXOC4 | c.270A>G p.I90M | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as COSV99556143; called by muse, mutect2
- EZH1 | c.448C>G p.L150V | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101331473; called by muse, mutect2
- FAM13A | c.1646C>A p.A549D | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99984903; called by muse, mutect2
- FAM89B | c.434C>T p.P145L (on ENST00000530349 / NM_001098785.2; = p.P132L on NM_152832.3) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs1391753085, COSV100326243; called by muse, mutect2
- FBXW9 | c.1376G>A p.G459D (on ENST00000587955; = p.G439D on NM_032301.3) | Missense Mutation (SNP) | VAF 14/307 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1335267152; called by muse, mutect2
- FGFR2 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs1196438732, COSV100337463; called by muse, mutect2
- FICD | c.1009T>C p.W337R | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99934544; called by muse, mutect2
- FLVCR2 | c.115G>A p.V39I | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.46); catalogued as COSV99471659; called by muse, mutect2
- FMNL3 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 43/507 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as rs746992567; called by muse, mutect2
- FRMPD3 | c.3361G>A p.V1121M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.138); catalogued as COSV99347336; called by muse, mutect2
- FRRS1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs932434241, COSV99790323; called by muse, mutect2
- GAB3 | c.523T>A p.S175T | Missense Mutation (SNP) | VAF 26/387 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV100850723; called by muse, mutect2
- GJC3 | c.824G>T p.G275V | Missense Mutation (SNP) | VAF 32/614 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV100458554; called by muse, mutect2
- GNE | c.1075+2T>C p.X359_splice (on ENST00000396594 / NM_001128227.3; = p.X328_splice on NM_005476.7 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 34/874 reads (4%) | catalogued as COSV100930163; called by muse, mutect2
- GNPAT | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.188); catalogued as rs1023890091, COSV100010084; called by muse, mutect2
- GOLGA1 | c.2123G>A p.C708Y | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52346883, COSV99414627; called by muse, mutect2
- GPATCH8 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 18/407 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100132941; called by muse, mutect2
- GPBAR1 | c.476C>G p.A159G | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.061); catalogued as COSV99946557; called by muse, varscan2
- GPD2 | c.680G>C p.R227P | Missense Mutation (SNP) | VAF 28/320 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60096057, COSV60096795; called by muse, mutect2
- GPR137B | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 28/938 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV63991401, COSV99053742; called by muse, mutect2
- GPRASP1 | c.466T>C p.Y156H | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.308); catalogued as COSV100851108; called by muse, mutect2
- GPRIN1 | c.1284C>G p.C428W | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV99992291; called by muse, mutect2, varscan2
- GRIA3 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 19/468 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52049378; called by muse, mutect2
- GRM1 | c.923T>A p.V308D | Missense Mutation (SNP) | VAF 22/373 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99269687; called by muse, mutect2
- HACD4 | c.82T>A p.F28I | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101529969; called by muse, mutect2
- HCN4 | c.2021G>A p.R674K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV99984377; called by muse, mutect2
- HERC1 | c.5209G>A p.E1737K | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.055); catalogued as COSV101497076; called by muse, mutect2
- HIVEP3 | c.5397G>C p.K1799N | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99914308; called by muse, mutect2, varscan2
- HIVEP3 | c.2740G>A p.A914T | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.158); catalogued as COSV99914311; called by muse, mutect2
- HIVEP3 | c.2236G>A p.A746T | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV99914313; called by muse, mutect2
- HKDC1 | c.408T>A p.D136E | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100664840; called by muse, mutect2, varscan2
- HNRNPM | c.1219G>A p.G407S | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.151); catalogued as COSV99725931; called by muse, mutect2
- HPCA | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 42/586 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs774794783, COSV100992215, COSV65102640; called by muse, mutect2
- HSD11B1 | c.791C>A p.T264N | Missense Mutation (SNP) | VAF 78/431 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0.082); catalogued as COSV99808423; called by muse, mutect2, varscan2
- HSPA5 | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as COSV100190176; called by muse, mutect2
- IGKV1D-8 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0.007); catalogued as rs527859306; called by muse, mutect2
- INPP5B | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV100886279; called by muse, mutect2
- IQGAP3 | c.2060C>T p.T687I | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100752466; called by muse, mutect2
- IQGAP3 | c.1907C>T p.A636V | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV100752467; called by muse, mutect2, varscan2
- IRF9 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs1460125657, COSV60704118; called by muse, mutect2
- ITSN1 | c.4393C>T p.H1465Y | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV101181031; called by muse, mutect2
- IVD | c.703C>T p.P235S (on ENST00000651168; = p.P232S on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV99991665; called by muse, mutect2
- KCNA4 | c.1869T>A p.C623* | Nonsense Mutation (SNP) | VAF 40/1025 reads (4%) | catalogued as COSV100069338; called by muse, mutect2
- KIAA2026 | c.6059T>A p.V2020D | Missense Mutation (SNP) | VAF 18/488 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.715); catalogued as COSV101199253; called by muse, mutect2
- KIF3C | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 86/258 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.023); catalogued as rs772693472, COSV99268030; called by muse, mutect2, varscan2
- KLHL9 | c.1346A>T p.Y449F | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV100757186; called by muse, mutect2
- KNTC1 | c.5854A>T p.K1952* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV100338915; called by muse, mutect2, varscan2
- LAMA3 | c.6925A>G p.I2309V (on ENST00000313654 / NM_198129.4; = p.I700V on NM_000227.6) | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV99336032; called by muse, mutect2, varscan2
- LAMC3 | c.734G>T p.G245V | Missense Mutation (SNP) | VAF 21/208 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63090705; called by muse, mutect2, varscan2
- LAP3 | c.1025A>T p.K342M | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV99884724; called by muse, mutect2
- LARP1 | c.1459C>T p.P487S (on ENST00000518297 / NM_033551.3; = p.P410S on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV100304221; called by muse, mutect2
- LMAN2 | c.195A>T p.Q65H | Missense Mutation (SNP) | VAF 40/323 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV100288532; called by muse, mutect2, varscan2
- LMBR1L | c.1436T>C p.F479S | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV99908966; called by muse, mutect2
- LNX1 | c.1400G>A p.R467Q (on ENST00000263925 / NM_001126328.3; = p.R371Q on NM_032622.2) | Missense Mutation (SNP) | VAF 17/251 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs771780717, COSV99820744; called by muse, mutect2
- LRP1 | c.9106C>T p.R3036W | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1157206291, COSV99677757; called by muse, mutect2, varscan2
- LRRC31 | c.266A>G p.K89R | Missense Mutation (SNP) | VAF 18/464 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52980193; called by muse, mutect2
- LRRC36 | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 65/1584 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.66); catalogued as COSV99339271; called by muse, mutect2
- LSM4 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.502); catalogued as rs1314035983, COSV53253733; called by muse, varscan2
- LY9 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 29/464 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1440752411, COSV99627620; called by muse, mutect2
- MAGED1 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100431913; called by muse, mutect2, varscan2
- MAP1B | c.515G>C p.G172A | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.351); catalogued as COSV99703052; called by muse, mutect2
- MAP3K4 | c.4805A>G p.K1602R | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100815751; called by muse, mutect2
- MAP4K4 | c.1817G>T p.G606V (on ENST00000347699 / NM_001242559.2; = p.G575V on NM_145686.3) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV100156157, COSV56341664; called by muse, mutect2
- MAPK8 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 26/674 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100827584; called by muse, mutect2
- MARF1 | c.4303G>A p.E1435K | Missense Mutation (SNP) | VAF 42/1022 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.06); catalogued as COSV100706508; called by muse, mutect2
- MBOAT1 | c.1466T>A p.I489N | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100209341; called by muse, mutect2
- MCCC2 | c.1604C>T p.A535V | Missense Mutation (SNP) | VAF 33/978 reads (3%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.024); catalogued as COSV100040635; called by muse, mutect2
- MCRS1 | c.116T>C p.L39S | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1392079525, COSV100657462; called by muse, mutect2
- MDN1 | c.11117T>C p.M3706T | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs1278226468, COSV101021931; called by muse, mutect2, varscan2
- MDN1 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101021933; called by muse, mutect2, varscan2
- MDN1 | c.507G>T p.W169C | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101021935; called by muse, mutect2
- MED12 | c.2584G>A p.G862S | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV100380385; called by muse, mutect2
- MGAT5 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99925258; called by muse, mutect2
- MIB1 | c.2278G>A p.A760T | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV99839640; called by muse, mutect2
- MICB | c.951G>A p.M317I | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.066); catalogued as rs1312883541, COSV52855812; called by muse, mutect2, varscan2
- MICB | c.1040A>G p.Q347R | Missense Mutation (SNP) | VAF 86/1728 reads (5%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.946); catalogued as COSV99357623; called by muse, mutect2
- MKRN3 | c.1120A>G p.S374G | Missense Mutation (SNP) | VAF 19/310 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100091807; called by muse, mutect2
- MPI | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 24/146 reads (16%) | catalogued as COSV100086413; called by muse, mutect2, varscan2
- MTA2 | c.296C>G p.A99G | Missense Mutation (SNP) | VAF 92/1937 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99604602; called by muse, mutect2
- MTOR | c.5274G>T p.Q1758H | Missense Mutation (SNP) | VAF 29/243 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as COSV100816784; called by muse, mutect2, varscan2
- MUC16 | c.38858G>C p.G12953A | Missense Mutation (SNP) | VAF 307/5918 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.877); catalogued as COSV101202172, COSV67467561; called by muse, mutect2
- MUC17 | c.719C>A p.P240H | Missense Mutation (SNP) | VAF 62/648 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs1247766087, COSV100075546; called by muse, mutect2
- MUC17 | c.7241C>T p.A2414V | Missense Mutation (SNP) | VAF 12/219 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV60288538; called by muse, mutect2
- MUC4 | c.1487G>T p.G496V | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as rs1299751708, COSV100642659; called by muse, mutect2
- MXRA5 | c.6458C>T p.P2153L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54252550, COSV54256768, COSV99479784; called by mutect2, varscan2
- MXRA5 | c.254T>C p.M85T | Missense Mutation (SNP) | VAF 10/207 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1285259161, COSV99479787; called by muse, mutect2
- MYBBP1A | c.3979A>G p.K1327E | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV99627296; called by muse, mutect2
- MYCL | c.1051C>G p.Q351E | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV100862413; called by muse, mutect2
- MYH10 | c.537G>C p.E179D | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV99346614; called by muse, mutect2
- MYH13 | c.2643G>T p.M881I | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV99355925; called by muse, mutect2
- MYH13 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 35/272 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.047); catalogued as COSV99355890; called by muse, mutect2, varscan2
- MYO5A | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 16/233 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.028); catalogued as COSV100698285; called by muse, mutect2
- MYO7B | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs1184467159, COSV101268433; called by muse, mutect2
- MYOF | c.2321A>T p.D774V | Missense Mutation (SNP) | VAF 19/187 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100826221; called by muse, mutect2
- MYOM3 | c.2391G>A p.W797* | Nonsense Mutation (SNP) | VAF 11/132 reads (8%) | catalogued as COSV100294068; called by muse, mutect2
- NADK2 | c.580C>G p.L194V (on ENST00000381937 / NM_001085411.3; = p.L31V on NM_153013.4) | Missense Mutation (SNP) | VAF 15/281 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1321511672, COSV99237997; called by muse, mutect2
- NCAPD3 | c.121A>T p.S41C | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV99845284; called by muse, mutect2
- NCOA6 | c.2519G>C p.S840T | Missense Mutation (SNP) | VAF 25/700 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.115); catalogued as COSV100750447; called by muse, mutect2
- NECTIN1 | c.650G>T p.R217M | Missense Mutation (SNP) | VAF 23/477 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99872772; called by muse, mutect2
- NF1 | c.2525G>A p.G842D | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100648509; called by muse, mutect2, varscan2
- NFIX | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 26/226 reads (12%) | catalogued as COSV100666671; called by muse, varscan2
- NLGN3 | c.1325G>T p.G442V (on ENST00000358741 / NM_181303.2; = p.G422V on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100705126; called by muse, mutect2
- NLRP10 | c.675G>A p.W225* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | catalogued as COSV100150032; called by muse, mutect2
- NLRP2 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 32/762 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.113); catalogued as COSV99672733; called by muse, mutect2
- NMRAL1 | c.860A>G p.Q287R | Missense Mutation (SNP) | VAF 27/512 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as COSV99361978; called by muse, mutect2
- NOL9 | c.491A>G p.D164G | Missense Mutation (SNP) | VAF 21/634 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as COSV100063634; called by muse, mutect2
- NOS2 | c.280A>G p.M94V | Missense Mutation (SNP) | VAF 30/567 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV100569948; called by muse, mutect2
- NR1D1 | c.1019C>G p.P340R | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.451); catalogued as COSV99225865; called by muse, mutect2, varscan2
- NRDE2 | c.1254G>A p.W418* | Nonsense Mutation (SNP) | VAF 13/102 reads (13%) | catalogued as COSV62963751; called by muse, mutect2, varscan2
- NRTN | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs202155391, COSV100294739; called by mutect2, varscan2
- NRXN2 | c.4058C>A p.T1353K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.643); catalogued as COSV99636387; called by mutect2, varscan2
- NUP50 | c.340+1G>A p.X114_splice | Splice Site (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100754434; called by muse, mutect2
- NUP98 | c.2086G>C p.A696P | Missense Mutation (SNP) | VAF 40/321 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV100263727; called by muse, mutect2, varscan2
- OGFRL1 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 22/570 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100965817; called by muse, mutect2
- OR10H1 | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 190/527 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.118); catalogued as COSV100612401; called by muse, mutect2, varscan2
- OR2L13 | c.12G>A p.W4* | Nonsense Mutation (SNP) | VAF 38/553 reads (7%) | catalogued as COSV100813911; called by muse, mutect2
- OR5D16 | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 16/545 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV101004061, COSV101004171; called by muse, mutect2
- OR6T1 | c.671C>T p.T224I | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100190248; called by muse, mutect2
- OR7A10 | c.820G>C p.A274P | Missense Mutation (SNP) | VAF 73/2258 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99932541; called by muse, mutect2
- P2RX7 | c.596C>A p.P199H | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99947844; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1027G>A p.G343S (on ENST00000259318 / NM_001136562.3; = p.G574S on NM_007203.5) | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.499); catalogued as COSV99395908; called by muse, mutect2
- PAN2 | c.2749G>A p.A917T (on ENST00000425394 / NM_001127460.3; = p.A913T on NM_014871.5) | Missense Mutation (SNP) | VAF 32/602 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV99228570; called by muse, mutect2
- PBXIP1 | c.1523A>T p.Q508L | Missense Mutation (SNP) | VAF 20/689 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV100870141; called by muse, mutect2
- PCDHB8 | c.2141T>C p.L714P | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV99177579; called by muse, mutect2
- PDAP1 | c.33A>T p.K11N | Missense Mutation (SNP) | VAF 18/152 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99769280; called by muse, mutect2
- PDE10A | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 13/308 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100606124; called by muse, mutect2
- PDE4DIP | c.2725G>T p.G909W | Missense Mutation (SNP) | VAF 28/622 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100522368; called by muse, mutect2
- PEAK1 | c.4817C>G p.P1606R | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100433567; called by muse, mutect2, varscan2
- PEG3 | c.4679A>T p.D1560V | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV99690848; called by muse, mutect2
- PHYH | c.83A>T p.H28L | Missense Mutation (SNP) | VAF 24/298 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as COSV99538423; called by muse, mutect2
- PIGU | c.163G>T p.V55L | Missense Mutation (SNP) | VAF 35/322 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as COSV54166662; called by muse, mutect2, varscan2
- PIGV | c.923A>G p.Q308R | Missense Mutation (SNP) | VAF 32/686 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1234266577, COSV99315213; called by muse, mutect2
- PIKFYVE | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 16/229 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV100011644; called by muse, mutect2
- PIP5K1C | c.1576A>G p.T526A | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.452); catalogued as COSV100096288; called by muse, mutect2, varscan2
- PKN2 | c.161G>A p.R54K | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV100281850; called by muse, mutect2
- PLA2G3 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.038); catalogued as COSV53209441, COSV99312167; called by muse, mutect2, varscan2
- PLA2G4F | c.2114T>C p.F705S | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV101215460; called by muse, mutect2
- PLCH1 | c.2105G>A p.G702D (on ENST00000340059 / NM_001130960.2; = p.G714D on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100398531; called by muse, mutect2
- POLQ | c.943C>G p.P315A | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV99953181; called by muse, mutect2
- POLR1A | c.3097C>T p.Q1033* | Nonsense Mutation (SNP) | VAF 20/154 reads (13%) | catalogued as COSV99808618; called by muse, varscan2
- POLRMT | c.221A>G p.Q74R | Missense Mutation (SNP) | VAF 18/269 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV101648695; called by muse, mutect2
- PPEF1 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 35/1017 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100584133; called by muse, mutect2
- PRDM1 | c.1735G>A p.V579I | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV64845214; called by muse, mutect2
- PRDM7 | c.203C>G p.A68G | Missense Mutation (SNP) | VAF 34/533 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV101344510; called by muse, mutect2
- PRKG2 | c.1787G>A p.G596E | Missense Mutation (SNP) | VAF 26/242 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100020717; called by muse, varscan2
- PRMT3 | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100424314; called by muse, mutect2
- PRPSAP1 | c.253C>A p.R85S | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100221798; called by muse, mutect2
- PRRC2C | c.7591C>T p.Q2531* (on ENST00000367742; = p.Q2529* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 42/828 reads (5%) | catalogued as COSV100146300; called by muse, mutect2
- PUS3 | c.346A>G p.R116G | Missense Mutation (SNP) | VAF 48/1369 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1371379452, COSV99917131; called by muse, mutect2
- QSOX1 | c.1082A>G p.Q361R | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.217); catalogued as COSV100852973; called by mutect2, varscan2
- RAD50 | c.1793+1G>A p.X598_splice | Splice Site (SNP) | VAF 16/220 reads (7%) | catalogued as COSV99529861; called by muse, mutect2
- RBM15 | c.2078G>A p.R693H | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); catalogued as rs539424286, COSV100873529; called by muse, mutect2, varscan2
- RBM4B | c.326T>C p.I109T | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV100026584; called by muse, mutect2
- REC8 | c.57G>T p.W19C | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100269328; called by muse, mutect2
- RFPL1 | c.944A>G p.E315G | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100585938; called by muse, mutect2
- RFX2 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs1387599225, COSV100354032; called by muse, mutect2
- RGS16 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV100842511; called by muse, mutect2
- RHOC | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 38/478 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs779142435, COSV99588595; called by muse, mutect2
- RHOC | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 19/242 reads (8%) | catalogued as COSV99588597; called by muse, mutect2
- RIN3 | c.62G>A p.G21D | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.71); PolyPhen benign (0.011); catalogued as COSV99380204; called by muse, mutect2
- RLN3 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 54/474 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1369780236, COSV54602542; called by muse, mutect2, varscan2
- RNASE13 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 42/574 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as rs1371726435, COSV100409697; called by muse, mutect2
- RND1 | c.170A>G p.E57G | Missense Mutation (SNP) | VAF 112/2172 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.173); catalogued as COSV100552255; called by muse, mutect2
- RNF207 | c.1483-1G>A p.X495_splice | Splice Site (SNP) | VAF 12/118 reads (10%) | catalogued as COSV65007639; called by muse, varscan2
- RNF216 | c.2494C>G p.P832A (on ENST00000425013 / NM_207116.3; = p.P889A on NM_207111.4) | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV101111408; called by muse, mutect2, varscan2
- ROBO4 | c.2639C>T p.A880V | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0.432); catalogued as COSV100127919; called by muse, mutect2
- RPGR | c.2507C>T p.T836I (on ENST00000339363 / NM_001367249.1; = p.T631I on NM_000328.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100140541; called by muse, mutect2, varscan2
- RSKR | c.670G>T p.G224C | Missense Mutation (SNP) | VAF 54/537 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1259132092, COSV99972368; called by muse, mutect2
- RSRC1 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 14/216 reads (6%) | catalogued as COSV55841228, COSV99907407; called by muse, mutect2
- SAMHD1 | c.533T>A p.L178Q | Missense Mutation (SNP) | VAF 20/556 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99484389; called by muse, mutect2
- SASH1 | c.3611G>A p.S1204N | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); catalogued as COSV66564180; called by muse, mutect2
- SCAMP5 | c.231G>A p.W77* | Nonsense Mutation (SNP) | VAF 80/1233 reads (6%) | catalogued as COSV100723876; called by muse, mutect2
- SCFD2 | c.382G>C p.G128R | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101189506; called by mutect2, varscan2
- SCML2 | c.746A>T p.N249I | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV99319608; called by muse, mutect2
- SDSL | c.842C>T p.A281V | Missense Mutation (SNP) | VAF 120/2028 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100615321, COSV61884363; called by muse, mutect2
- SEC23A | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV100305941; called by muse, mutect2
- SEC31A | c.3188T>C p.F1063S (on ENST00000355196 / NM_001318120.1; = p.F1024S on NM_016211.4) | Missense Mutation (SNP) | VAF 26/459 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.276); catalogued as COSV100022428; called by muse, mutect2
- SEL1L3 | c.1411A>G p.R471G | Missense Mutation (SNP) | VAF 23/217 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99341480; called by muse, mutect2
- SELENON | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100823603; called by muse, mutect2, varscan2
- SERINC4 | c.1523T>A p.I508N | Missense Mutation (SNP) | VAF 55/513 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.467); catalogued as COSV99988737; called by muse, mutect2, varscan2
- SERPINF2 | c.1297G>A p.V433M | Missense Mutation (SNP) | VAF 46/526 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757681136, COSV100132152; called by muse, mutect2
- SESN2 | c.502C>T p.H168Y | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99456311; called by muse, mutect2, varscan2
- SETD5 | c.2750T>C p.L917S | Missense Mutation (SNP) | VAF 73/2294 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.207); catalogued as COSV100201234; called by muse, mutect2
- SF3B3 | c.3018A>T p.Q1006H | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); catalogued as COSV100210351; called by muse, mutect2
- SGPP2 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100347062; called by muse, mutect2
- SHC4 | c.895-2A>G p.X299_splice | Splice Site (SNP) | VAF 8/117 reads (7%) | catalogued as rs1455010632; called by muse, mutect2
- SIDT2 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.66); catalogued as COSV99638655; called by muse, mutect2, varscan2
- SIRPG | c.64G>T p.G22* | Nonsense Mutation (SNP) | VAF 17/336 reads (5%) | catalogued as COSV99404072; called by muse, mutect2
- SIRT2 | c.8A>G p.E3G | Missense Mutation (SNP) | VAF 16/244 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV99979680; called by muse, mutect2
- SLC15A2 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 21/410 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99815935; called by muse, mutect2
- SLC22A16 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 50/678 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57935461; called by muse, mutect2
- SLC22A23 | c.1739G>A p.G580D | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100978465; called by muse, mutect2, varscan2
- SLC22A7 | c.749T>A p.V250D (on ENST00000372585 / NM_153320.2; = p.V248D on NM_006672.3) | Missense Mutation (SNP) | VAF 71/421 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV101000882; called by muse, mutect2, varscan2
- SLC34A1 | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.387); catalogued as COSV100184188; called by muse, mutect2
- SLC38A4 | c.1151T>A p.L384H | Missense Mutation (SNP) | VAF 14/404 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99873293; called by muse, mutect2
- SLC39A6 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 25/333 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99310016; called by muse, mutect2
- SLC44A3 | c.1115C>A p.P372H (on ENST00000271227 / NM_001114106.3; = p.P324H on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.911); catalogued as rs1237460553; called by muse, mutect2
- SLC7A9 | c.277T>C p.S93P | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99195550; called by mutect2, varscan2
- SLC9C1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.489); catalogued as rs1423530120, COSV99998991; called by muse, mutect2
- SLITRK3 | c.1636G>C p.G546R | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53854930, COSV99580373; called by muse, mutect2, varscan2
- SLMAP | c.2078A>T p.E693V (on ENST00000428312 / NM_001377924.1; = p.E755V on NM_007159.5) | Missense Mutation (SNP) | VAF 8/168 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99909417; called by muse, mutect2
- SLU7 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 38/1026 reads (4%) | catalogued as COSV99775882; called by muse, mutect2
- SMG1 | c.6893A>G p.K2298R | Missense Mutation (SNP) | VAF 34/670 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.048); catalogued as COSV101247002; called by muse, mutect2
- SMG5 | c.897G>C p.Q299H | Missense Mutation (SNP) | VAF 102/703 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV100700951; called by muse, mutect2, varscan2
- SORCS1 | c.2083A>G p.K695E | Missense Mutation (SNP) | VAF 23/632 reads (4%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.718); catalogued as COSV99551225; called by muse, mutect2
- SPN | c.248C>G p.A83G | Missense Mutation (SNP) | VAF 43/668 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.072); catalogued as COSV100788927; called by muse, mutect2
- SPOCD1 | c.2278C>T p.Q760* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as COSV99930451; called by muse, mutect2, varscan2
- SPPL2C | c.1171T>A p.F391I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100234214; called by muse, mutect2, varscan2
- SSH3 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57385226; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | PolyPhen benign (0.005); catalogued as COSV100231625; called by muse, mutect2, varscan2
- STK10 | c.193A>G p.K65E | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99452491; called by muse, mutect2, varscan2
- SUCLA2 | c.1361T>A p.L454* (on ENST00000643023; = p.L433* on NM_003850.3) | Nonsense Mutation (SNP) | VAF 31/1071 reads (3%) | catalogued as COSV101075003; called by muse, mutect2
- SURF1 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.087); catalogued as rs1469895982, COSV100034894; called by muse, mutect2, varscan2
- SYNCRIP | c.422A>T p.Q141L | Missense Mutation (SNP) | VAF 21/346 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100784370; called by muse, mutect2
- SYTL2 | c.1822T>A p.L608M (on ENST00000528231 / NM_001162951.2; = p.L1897M on NM_206927.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/1246 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.729); catalogued as COSV100315095; called by muse, mutect2
- TAF6L | c.716T>C p.V239A | Missense Mutation (SNP) | VAF 25/247 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV99585519; called by muse, mutect2, varscan2
- TDRD9 | c.1520G>A p.R507Q | Missense Mutation (SNP) | VAF 19/464 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1566775451, COSV100175827; called by muse, mutect2
- TECTA | c.4832G>A p.S1611N | Missense Mutation (SNP) | VAF 13/268 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.315); catalogued as COSV99881911; called by muse, mutect2
- TEKT1 | c.1202A>G p.D401G | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as COSV100106515; called by muse, mutect2, varscan2
- TENT5B | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 4/81 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV56693969; called by muse, mutect2
- TEX19 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs868177850, COSV100331105; called by muse, mutect2, varscan2
- TFEB | c.761G>A p.R254H | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57824905; called by muse, mutect2, varscan2
- THAP4 | c.1605C>G p.H535Q | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.321); catalogued as rs1190566911, COSV100398344; called by muse, mutect2
- THAP4 | c.805T>C p.C269R | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV101126119; called by muse, mutect2
- THEM5 | c.571A>G p.K191E | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.442); catalogued as COSV100917302; called by muse, mutect2
- THOC2 | c.3566A>G p.K1189R | Missense Mutation (SNP) | VAF 24/692 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV99834444; called by muse, mutect2
- THOC2 | c.2479T>C p.S827P | Missense Mutation (SNP) | VAF 46/821 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as COSV99834445; called by muse, mutect2
- THRA | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 212/1107 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV99225860; called by muse, mutect2, varscan2
- THSD7A | c.2995C>T p.R999C | Missense Mutation (SNP) | VAF 48/1281 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1213861708, COSV70264819, COSV70264976; called by muse, mutect2
- TLE3 | c.679C>T p.R227W | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs369770103; called by muse, mutect2, varscan2
- TMEM268 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV99938859; called by muse, mutect2
- TMSB15A | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 9/182 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.849); catalogued as COSV99179207; called by muse, mutect2
- TNC | c.5528G>A p.R1843H | Missense Mutation (SNP) | VAF 32/440 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.103); catalogued as rs200602864, COSV60783649; called by muse, mutect2
- TNC | c.4277C>T p.T1426I | Missense Mutation (SNP) | VAF 44/854 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100406453; called by muse, mutect2
- TNKS1BP1 | c.3298G>A p.A1100T | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.046); catalogued as rs1461490018, COSV100835887; called by muse, mutect2, varscan2
- TNN | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.018); catalogued as COSV99513325; called by muse, mutect2, varscan2
- TNRC18 | c.8597G>A p.S2866N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.88); PolyPhen benign (0.013); catalogued as rs746559857, COSV100079190; called by mutect2, varscan2
- TNRC18 | c.5246A>T p.Q1749L | Missense Mutation (SNP) | VAF 79/302 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV101269919; called by muse, mutect2, varscan2
- TNRC6C | c.3946dup p.L1316Pfs*6 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | catalogued as rs1316060576; called by pindel, varscan2
- TNS4 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54188655; called by muse, mutect2
- TOR3A | c.1132C>G p.Q378E | Missense Mutation (SNP) | VAF 34/1124 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV100751439; called by muse, mutect2
- TPX2 | c.938A>G p.K313R | Missense Mutation (SNP) | VAF 12/311 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1568595841; called by muse, mutect2
- TRAF1 | c.313C>A p.Q105K | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100875227; called by muse, mutect2, varscan2
- TRANK1 | c.7800G>A p.M2600I | Missense Mutation (SNP) | VAF 268/330 reads (81%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs1264579412, COSV57155634; called by muse, mutect2, varscan2
- TRANK1 | c.5716G>A p.A1906T | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100085210; called by muse, mutect2
- TRIM65 | c.1018G>A p.A340T | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755830443, COSV99485638; called by muse, mutect2, varscan2
- TRMO | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100796015; called by muse, mutect2
- TRPV3 | c.1184T>A p.V395E | Missense Mutation (SNP) | VAF 31/418 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV100028255; called by muse, mutect2
- TRRAP | c.10649G>A p.R3550H (on ENST00000359863 / NM_001244580.1; = p.R3521H on NM_003496.3) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1190818340, COSV100723209; called by muse, mutect2, varscan2
- TTBK2 | c.3206C>T p.T1069I | Missense Mutation (SNP) | VAF 28/894 reads (3%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as COSV99142691; called by muse, mutect2
- TTC21A | c.2362G>A p.A788T | Missense Mutation (SNP) | VAF 29/267 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs747683572, COSV100087808; called by muse, mutect2, varscan2
- TTLL2 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 306/3110 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99515026; called by mutect2, varscan2
- TTN | c.15650G>A p.S5217N (on ENST00000591111; = p.S4290N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/264 reads (4%) | PolyPhen benign (0.079); catalogued as COSV60165845; called by muse, mutect2
- TUBB4A | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 54/298 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as COSV99900213; called by muse, varscan2
- UBA1 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 75/528 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.845); catalogued as rs782776898, COSV100256207; called by muse, mutect2, varscan2
- UBA6 | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | catalogued as COSV100452003; called by muse, mutect2
- UBE2G2 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100446190; called by muse, mutect2, varscan2
- UBR4 | c.4115T>A p.L1372Q | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100922160; called by muse, mutect2
- UGGT2 | c.1193A>T p.D398V | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100948985; called by muse, mutect2
- USP26 | c.1475T>G p.L492R | Missense Mutation (SNP) | VAF 46/780 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100896799; called by muse, mutect2
- USP34 | c.7954C>T p.R2652* | Nonsense Mutation (SNP) | VAF 111/369 reads (30%) | catalogued as COSV68408046; called by muse, mutect2, varscan2
- UTP20 | c.1019C>T p.T340M | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs373233138; called by muse, mutect2, varscan2
- VASH2 | c.622G>T p.G208C (on ENST00000517399 / NM_001301056.2; = p.G164C on NM_024749.5) | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99663752; called by muse, mutect2, varscan2
- VIL1 | c.607G>A p.G203R | Missense Mutation (SNP) | VAF 14/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99945949; called by muse, mutect2
- VPS8 | c.2260C>G p.Q754E (on ENST00000625842 / NM_001349294.1; = p.Q752E on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/616 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.247); catalogued as COSV99804397; called by muse, mutect2
- WDR77 | c.763T>C p.S255P | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.588); catalogued as COSV99331018; called by muse, mutect2
- WDR88 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as rs1222372306, COSV100866657; called by muse, mutect2
- WDTC1 | c.1595G>A p.G532D (on ENST00000319394 / NM_001276252.2; = p.G531D on NM_015023.5) | Missense Mutation (SNP) | VAF 33/658 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60090774; called by muse, mutect2
- WNT11 | c.149G>A p.G50D | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100490477; called by muse, mutect2, varscan2
- XIRP1 | c.1364A>G p.Q455R | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV100454063; called by muse, mutect2
- ZBTB3 | c.964C>T p.Q322* | Nonsense Mutation (SNP) | VAF 59/574 reads (10%) | catalogued as COSV101189019; called by muse, mutect2, varscan2
- ZEB2 | c.2407C>T p.P803S | Missense Mutation (SNP) | VAF 13/270 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV100357221; called by muse, mutect2
- ZFP69B | c.1309C>G p.H437D | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100848319; called by muse, mutect2, varscan2
- ZIC4 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 26/852 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.157); catalogued as COSV101268008, COSV101268081; called by muse, mutect2
- ZMYND8 | c.1165G>A p.A389T (on ENST00000311275 / NM_001363741.2; = p.A409T on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/1309 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as COSV99519751; called by muse, mutect2
- ZNF155 | c.925G>T p.V309F | Missense Mutation (SNP) | VAF 14/301 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99525845; called by muse, mutect2
- ZNF398 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV100247110; called by muse, mutect2
- ZNF780A | c.1154G>A p.G385D | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.875); catalogued as rs1261005225, COSV100575289; called by muse, mutect2
- ZNF8 | c.770A>G p.Y257C | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99544632; called by muse, mutect2, varscan2
- ABCB4 | c.779T>G p.L260R | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ADAM22 | c.1684G>A p.V562M | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); called by muse, mutect2
- ADD2 | c.1684G>A p.D562N | Missense Mutation (SNP) | VAF 18/477 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- AP002512.3 | c.667T>C p.F223L | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.159); called by muse, mutect2
- AP002748.5 | c.1654C>A p.L552M | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2
- B4GALT3 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 16/502 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.166); called by muse, mutect2
- BMP2K | c.179-2A>T p.X60_splice | Splice Site (SNP) | VAF 10/254 reads (4%) | called by muse, mutect2
- C11orf16 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- CCDC8 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); called by muse, mutect2
- CCL14 | c.107G>A p.C36Y (on ENST00000618404 / NM_032963.4; = p.C52Y on NM_032962.4) | Missense Mutation (SNP) | VAF 26/484 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCR10 | c.35del p.G12Afs*38 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | called by mutect2, pindel, varscan2
- CEP164 | c.2080G>A p.A694T | Missense Mutation (SNP) | VAF 16/482 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2
- CFAP92 | c.551T>C p.F184S | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.23); called by muse, mutect2
- CHCHD2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.222); called by muse, mutect2
- CHD1L | c.2590G>A p.A864T | Missense Mutation (SNP) | VAF 35/754 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.587); called by muse, mutect2
- CHI3L1 | c.569A>G p.D190G | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2
- CILK1 | c.1100A>C p.D367A | Missense Mutation (SNP) | VAF 24/607 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- COL5A1 | c.439C>A p.P147T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL6A3 | c.9045dup p.G3016Rfs*6 | Frame Shift Ins (INS) | VAF 17/145 reads (12%) | called by mutect2, pindel, varscan2
- CXXC4 | c.731dup p.I245Hfs*95 | Frame Shift Ins (INS) | VAF 11/110 reads (10%) | called by mutect2, varscan2
- DECR1 | c.236T>C p.L79P | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- ERBB2 | c.3318del p.S1107Afs*25 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- ERBB3 | c.2577del p.P860Lfs*40 | Frame Shift Del (DEL) | VAF 88/870 reads (10%) | called by mutect2, pindel, varscan2
- EVPL | c.3792dup p.E1265Rfs*5 | Frame Shift Ins (INS) | VAF 6/53 reads (11%) | called by mutect2, pindel, varscan2
- FER1L5 | c.5182C>T p.P1728S (on ENST00000623019; = p.P1701S on NM_001293083.2) | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- GCAT | c.1148dup p.K385Qfs*13 | Frame Shift Ins (INS) | VAF 17/83 reads (20%) | called by mutect2, pindel, varscan2
- GIMAP8 | c.118T>A p.F40I | Missense Mutation (SNP) | VAF 16/509 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2
- GLG1 | c.3511C>T p.R1171* | Nonsense Mutation (SNP) | VAF 20/750 reads (3%) | called by muse, mutect2
- GPR179 | c.6337G>A p.A2113T (on ENST00000621958; = p.A2112T on NM_001004334.4) | Missense Mutation (SNP) | VAF 44/750 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.069); called by muse, mutect2
- GTF3C1 | c.1187dup p.L398Tfs*72 | Frame Shift Ins (INS) | VAF 12/140 reads (9%) | called by mutect2, pindel
- H1-8 | c.839dup p.K281Efs*10 | Frame Shift Ins (INS) | VAF 13/100 reads (13%) | called by mutect2, pindel, varscan2
- HPS5 | c.110G>A p.C37Y | Missense Mutation (SNP) | VAF 14/366 reads (4%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.98); called by muse, mutect2
- IL5RA | c.407C>T p.T136I | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.625); called by muse, mutect2
- INPP5D | c.1226G>A p.G409D (on ENST00000445964 / NM_001017915.3; = p.G408D on NM_005541.5) | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- IQCF1 | c.342del p.Q115Rfs*4 | Frame Shift Del (DEL) | VAF 16/102 reads (16%) | called by mutect2, pindel, varscan2
- ITPRIP | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- KCNA2 | c.377T>G p.F126C | Missense Mutation (SNP) | VAF 134/167 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- KDM3A | c.3114dup p.E1039Rfs*8 | Frame Shift Ins (INS) | VAF 10/75 reads (13%) | called by mutect2, pindel, varscan2
- KRBOX4 | c.216dup p.T73Dfs*9 (on ENST00000344302 / NM_001129898.2; = p.T73Dfs*13 on NM_017776.2) | Frame Shift Ins (INS) | VAF 41/348 reads (12%) | called by mutect2, pindel, varscan2
- KRT78 | c.1231G>C p.A411P | Missense Mutation (SNP) | VAF 18/628 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- LRP1 | c.2364dup p.I789Hfs*3 | Frame Shift Ins (INS) | VAF 55/435 reads (13%) | called by mutect2, pindel, varscan2
- LRP2 | c.13355G>A p.G4452D | Missense Mutation (SNP) | VAF 16/546 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- LTBP3 | c.1784dup p.D596* | Frame Shift Ins (INS) | VAF 13/118 reads (11%) | called by mutect2, pindel
- MAP4 | c.2878dup p.T960Nfs*11 | Frame Shift Ins (INS) | VAF 41/230 reads (18%) | called by mutect2, varscan2
- MCTP2 | c.1420T>C p.S474P | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MPDU1 | c.169+2T>C p.X57_splice | Splice Site (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- MYEF2 | c.1650G>A p.M550I | Missense Mutation (SNP) | VAF 10/201 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.041); called by muse, mutect2
- NBPF11 | c.1818A>T p.Q606H | Missense Mutation (SNP) | VAF 112/3614 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.031); called by muse, mutect2
- NFE2L2 | c.1492A>T p.I498F | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- NRAP | c.1736G>A p.S579N (on ENST00000359988 / NM_001322945.2; = p.S544N on NM_006175.4) | Missense Mutation (SNP) | VAF 30/1173 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OSMR | c.1450C>T p.H484Y | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2
- PIK3C2B | c.1839dup p.G614Rfs*6 | Frame Shift Ins (INS) | VAF 59/520 reads (11%) | called by mutect2, pindel, varscan2
- PLAA | c.1120T>C p.W374R | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PMFBP1 | c.465G>T p.E155D | Missense Mutation (SNP) | VAF 13/355 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.021); called by muse, mutect2
- PTPRO | c.2720dup p.N907Kfs*16 (on ENST00000281171 / NM_030667.3; = p.N879Kfs*16 on NM_002848.4) | Frame Shift Ins (INS) | VAF 18/185 reads (10%) | called by mutect2, pindel
- RAB23 | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 45/808 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RABGAP1 | c.1697G>A p.G566D | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RBM42 | c.536G>A p.G179D | Missense Mutation (SNP) | VAF 10/242 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2
- RBP3 | c.3203G>A p.W1068* | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- RESF1 | c.1412C>T p.T471I | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.127); called by muse, mutect2
- RYK | c.431G>A p.G144E | Missense Mutation (SNP) | VAF 15/470 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEC31B | c.587G>A p.W196* | Nonsense Mutation (SNP) | VAF 38/560 reads (7%) | called by muse, mutect2
- SETD2 | c.5977G>A p.E1993K | Missense Mutation (SNP) | VAF 22/424 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- SLC26A9 | c.2196del p.D732Efs*13 | Frame Shift Del (DEL) | VAF 132/1022 reads (13%) | called by mutect2, pindel, varscan2
- SLC38A11 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.93); called by muse, mutect2
- SMTN | c.596C>A p.S199Y | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, varscan2
- SPAG17 | c.5636C>T p.S1879L | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.024); called by muse, mutect2
- SPATA6L | c.89G>A p.G30E | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2
- SPINK9 | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 24/695 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- STAT3 | c.1135A>G p.R379G | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- SUCLA2 | c.973G>A p.A325T (on ENST00000643023; = p.A304T on NM_003850.3) | Missense Mutation (SNP) | VAF 16/311 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SZT2 | c.5138dup p.I1714Hfs*16 (on ENST00000634258 / NM_001365999.1; = p.I1657Hfs*16 on NM_015284.4) | Frame Shift Ins (INS) | VAF 13/84 reads (15%) | called by mutect2, pindel, varscan2
- TARBP2 | c.1006G>A p.V336M (on ENST00000266987 / NM_134323.2; = p.V315M on NM_004178.4) | Missense Mutation (SNP) | VAF 15/171 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- TAS1R2 | c.1802dup p.M603Hfs*107 | Frame Shift Ins (INS) | VAF 12/118 reads (10%) | called by mutect2, pindel
- TG | c.374A>G p.D125G | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2
- THSD4 | c.1078C>T p.Q360* | Nonsense Mutation (SNP) | VAF 28/346 reads (8%) | called by muse, mutect2
- TLL1 | c.995T>A p.L332Q | Missense Mutation (SNP) | VAF 33/562 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- TRAV19 | c.277A>T p.S93C | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- TRPC3 | c.454C>T p.Q152* (on ENST00000379645 / NM_001366479.2; = p.Q79* on NM_003305.2) | Nonsense Mutation (SNP) | VAF 9/204 reads (4%) | called by muse, mutect2
- TTN | c.37211C>T p.A12404V (on ENST00000591111; = p.A4980V on NM_003319.4) | Missense Mutation (SNP) | VAF 7/107 reads (7%) | PolyPhen probably damaging (0.96); called by muse, mutect2
- YIF1B | c.317T>C p.I106T (on ENST00000339413 / NM_001039673.3; = p.I91T on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.207); called by muse, mutect2
- ZC3H15 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF765 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 34/1241 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2
- ABCC2 | c.2415C>T p.G805= | Silent (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- ADAMTS4 | c.726G>A p.L242= | Silent (SNP) | VAF 120/732 reads (16%) | called by mutect2, varscan2
- ADCY1 | c.547C>T p.L183= | Silent (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- ADGRG4 | c.3597C>T p.S1199= | Silent (SNP) | VAF 34/972 reads (3%) | catalogued as COSV99797407; called by muse, mutect2
- AGFG2 | c.930G>A p.Q310= | Silent (SNP) | VAF 16/188 reads (9%) | catalogued as COSV99499631; called by muse, mutect2
- ALAS1 | c.69C>A p.G23= | Silent (SNP) | VAF 14/241 reads (6%) | catalogued as COSV100050527; called by muse, mutect2
- ALDH18A1 | c.1866G>A p.R622= | Silent (SNP) | VAF 8/218 reads (4%) | called by muse, mutect2
- AMOTL2 | c.1062G>A p.R354= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99998376; called by muse, mutect2, varscan2
- AMPD1 | c.1389C>A p.G463= | Silent (SNP) | VAF 25/560 reads (4%) | catalogued as COSV100815342; called by muse, mutect2
- ANKRD17 | c.6039C>T p.V2013= | Silent (SNP) | VAF 32/874 reads (4%) | catalogued as COSV100430137; called by muse, mutect2
- APLNR | c.756G>A p.V252= | Silent (SNP) | VAF 16/423 reads (4%) | catalogued as rs1354560565, COSV99951724; called by muse, mutect2
- ARHGAP24 | c.1911C>T p.S637= (on ENST00000395184 / NM_001025616.3; = p.S544= on NM_031305.3) | Silent (SNP) | VAF 18/349 reads (5%) | catalogued as COSV99982518; called by muse, mutect2
- ARL3 | c.381G>A p.K127= | Silent (SNP) | VAF 26/351 reads (7%) | catalogued as COSV99589198; called by muse, mutect2
- ARMC9 | c.645G>A p.Q215= | Silent (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2
- ARSG | c.151C>T p.L51= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV101477936; called by muse, mutect2, varscan2
- BCL2L14 | c.759C>T p.V253= | Silent (SNP) | VAF 24/788 reads (3%) | called by muse, mutect2
- BDP1 | c.5136C>T p.G1712= | Silent (SNP) | VAF 18/246 reads (7%) | catalogued as COSV100703673; called by muse, mutect2
- BMX | c.1695G>A p.Q565= | Silent (SNP) | VAF 13/316 reads (4%) | catalogued as COSV100564701; called by muse, mutect2
- BPIFB6 | c.861C>T p.P287= | Silent (SNP) | VAF 74/1286 reads (6%) | catalogued as COSV100848564; called by muse, mutect2
- BSN | c.3825A>T p.S1275= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV99610152; called by muse, mutect2, varscan2
- BTBD11 | c.2706A>G p.T902= (on ENST00000280758 / NM_001018072.2; = p.T439= on NM_001017523.2) | Silent (SNP) | VAF 14/284 reads (5%) | called by muse, mutect2
- C3 | c.3666C>T p.D1222= | Silent (SNP) | VAF 42/1586 reads (3%) | catalogued as COSV99837430; called by muse, mutect2
- CALCR | c.1009C>A p.R337= (on ENST00000649521 / NM_001164737.2; = p.R321= on NM_001742.4) | Silent (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- CAPNS1 | c.651C>T p.Y217= | Silent (SNP) | VAF 22/512 reads (4%) | catalogued as COSV99497172; called by muse, mutect2
- CBLL2 | c.480A>G p.P160= | Silent (SNP) | VAF 28/640 reads (4%) | catalogued as COSV100081804; called by muse, mutect2
- CCDC54 | c.555T>A p.S185= | Silent (SNP) | VAF 16/450 reads (4%) | catalogued as COSV99660350; called by muse, mutect2
- CCDC57 | c.2418C>G p.P806= | Silent (SNP) | VAF 21/118 reads (18%) | catalogued as COSV101052138, COSV66438082; called by muse, mutect2, varscan2
- CCNB3 | c.4110C>T p.A1370= | Silent (SNP) | VAF 9/173 reads (5%) | catalogued as rs1557221204; called by muse, mutect2
- CD37 | c.669C>T p.S223= | Silent (SNP) | VAF 10/192 reads (5%) | catalogued as COSV100114807; called by muse, mutect2
- CELSR2 | c.7338G>A p.L2446= | Silent (SNP) | VAF 12/115 reads (10%) | catalogued as COSV99604987; called by muse, mutect2, varscan2
- CFAP43 | c.2736G>C p.A912= | Silent (SNP) | VAF 24/219 reads (11%) | catalogued as COSV53378499, COSV99531115; called by muse, mutect2, varscan2
- CHAF1A | c.1962T>C p.P654= | Silent (SNP) | VAF 44/492 reads (9%) | catalogued as COSV100011567; called by muse, mutect2
- CHRND | c.1062C>T p.T354= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- COL22A1 | c.2883C>T p.G961= | Silent (SNP) | VAF 7/76 reads (9%) | catalogued as COSV57331249, COSV57356874; called by muse, mutect2
- CTC1 | c.3507C>G p.V1169= | Silent (SNP) | VAF 47/1060 reads (4%) | catalogued as COSV100236906; called by muse, mutect2
- CUL9 | c.3084A>G p.A1028= | Silent (SNP) | VAF 97/2593 reads (4%) | catalogued as rs896727575, COSV99336203; called by muse, mutect2
- CYTH4 | c.861C>T p.C287= | Silent (SNP) | VAF 22/292 reads (8%) | catalogued as COSV50631540; called by muse, mutect2
- DCTN1 | c.1485G>A p.R495= | Silent (SNP) | VAF 10/227 reads (4%) | catalogued as COSV100720856, COSV100721127; called by muse, mutect2
- DENND10 | c.129G>A p.L43= | Silent (SNP) | VAF 27/997 reads (3%) | called by muse, mutect2
- DGKK | c.3672G>A p.L1224= | Silent (SNP) | VAF 1724/1821 reads (95%) | catalogued as COSV101053269; called by muse, mutect2, varscan2
- DHTKD1 | c.615G>A p.L205= | Silent (SNP) | VAF 100/582 reads (17%) | catalogued as COSV99537027; called by muse, mutect2, varscan2
- DHX37 | c.843G>A p.K281= | Silent (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2, varscan2
- DIO1 | c.162C>T p.P54= | Silent (SNP) | VAF 28/1019 reads (3%) | called by muse, mutect2
- DLEC1 | c.4389G>A p.V1463= | Silent (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100343757; called by muse, mutect2, varscan2
- DLGAP2 | c.2412G>A p.Q804= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV101423031; called by muse, mutect2, varscan2
- DNAJC5 | c.204G>A p.T68= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs1002205118; ClinVar: uncertain significance; called by muse, varscan2
- DNTT | c.1344A>G p.G448= | Silent (SNP) | VAF 21/516 reads (4%) | catalogued as COSV100960808; called by muse, mutect2
- DSCAML1 | c.4122G>A p.V1374= (on ENST00000321322; = p.V1314= on NM_020693.4) | Silent (SNP) | VAF 18/353 reads (5%) | called by muse, mutect2
- DTX3 | c.15G>A p.L5= | Silent (SNP) | VAF 54/955 reads (6%) | catalogued as COSV99678392; called by muse, mutect2
- DYSF | c.5010G>A p.L1670= | Silent (SNP) | VAF 63/1284 reads (5%) | catalogued as rs745944313; called by muse, mutect2
- EEF2K | c.807G>A p.Q269= | Silent (SNP) | VAF 84/225 reads (37%) | catalogued as COSV99533813; called by muse, varscan2
- EEFSEC | c.1515G>A p.G505= | Silent (SNP) | VAF 12/218 reads (6%) | catalogued as COSV99631644; called by muse, mutect2
- EIF3E | c.48G>T p.R16= | Silent (SNP) | VAF 390/2390 reads (16%) | catalogued as COSV99623639; called by muse, mutect2, varscan2
- ELP2 | c.2226A>G p.V742= | Silent (SNP) | VAF 5/43 reads (12%) | called by muse, varscan2
- EVX2 | c.759G>A p.P253= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV57964364; called by muse, mutect2, varscan2
- EWSR1 | c.1074T>C p.S358= | Silent (SNP) | VAF 23/488 reads (5%) | catalogued as COSV100132205; called by muse, mutect2
- FAM122A | c.537G>A p.T179= | Silent (SNP) | VAF 11/142 reads (8%) | called by muse, mutect2
- FANCD2OS | c.111C>T p.P37= | Silent (SNP) | VAF 87/417 reads (21%) | catalogued as rs80267386, COSV101092052; called by muse, mutect2, varscan2
- FMNL1 | c.1305G>A p.Q435= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100057094; called by muse, mutect2, varscan2
- FMO3 | c.504C>T p.G168= | Silent (SNP) | VAF 26/239 reads (11%) | catalogued as COSV100882566; called by muse, mutect2, varscan2
- GBA | c.1113C>T p.P371= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs749633975, COSV100516520; called by muse, mutect2, varscan2
- GGA3 | c.681G>A p.L227= (on ENST00000537686 / NM_138619.4; = p.L194= on NM_014001.5) | Silent (SNP) | VAF 38/638 reads (6%) | catalogued as COSV99822413; called by muse, mutect2
- GGCX | c.1116G>T p.L372= | Silent (SNP) | VAF 15/347 reads (4%) | catalogued as COSV99290278; called by muse, mutect2
- GNA15 | c.951G>A p.T317= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs866982833, COSV99505502; called by muse, mutect2, varscan2
- GPM6A | c.105G>A p.L35= | Silent (SNP) | VAF 38/908 reads (4%) | catalogued as COSV54560271, COSV99706027; called by muse, mutect2
- GTF3C2 | c.1722A>T p.G574= | Silent (SNP) | VAF 18/352 reads (5%) | catalogued as COSV99273413; called by muse, mutect2
- HAVCR1 | c.207C>A p.V69= | Silent (SNP) | VAF 12/204 reads (6%) | catalogued as COSV100208692; called by muse, mutect2
- HAVCR2 | c.570T>C p.N190= | Silent (SNP) | VAF 74/662 reads (11%) | catalogued as COSV100325050; called by muse, mutect2, varscan2
- HDHD3 | c.690C>A p.I230= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV99444927; called by muse, mutect2
- HECA | c.522C>T p.R174= | Silent (SNP) | VAF 26/690 reads (4%) | catalogued as COSV100866278; called by muse, mutect2
- HOMER1 | c.312G>A p.Q104= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as COSV56526030, COSV99981599; called by muse, mutect2
- HUWE1 | c.7080C>T p.G2360= | Silent (SNP) | VAF 8/174 reads (5%) | catalogued as rs1290999831, COSV53350622; called by muse, mutect2
- IFT81 | c.1956C>T p.C652= | Silent (SNP) | VAF 18/396 reads (5%) | catalogued as COSV99656471; called by muse, mutect2
- ILF3 | c.1419C>T p.G473= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99140453; called by muse, mutect2, varscan2
- INSR | c.843G>A p.V281= | Silent (SNP) | VAF 44/402 reads (11%) | catalogued as COSV100253814; called by muse, mutect2, varscan2
- JHY | c.1587C>T p.L529= | Silent (SNP) | VAF 9/186 reads (5%) | catalogued as COSV99913526; called by muse, mutect2
- KHDC3L | c.270T>C p.F90= | Silent (SNP) | VAF 56/443 reads (13%) | catalogued as COSV100951173; called by muse, mutect2, varscan2
- KIF17 | c.687C>T p.D229= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV99929961; called by muse, mutect2, varscan2
- KRTAP23-1 | c.18C>T p.C6= | Silent (SNP) | VAF 36/898 reads (4%) | catalogued as COSV100492674; called by muse, mutect2
- LARGE1 | c.1521C>T p.D507= | Silent (SNP) | VAF 6/95 reads (6%) | catalogued as rs1312649028, COSV100505248; called by muse, mutect2
- LILRB5 | c.1548A>T p.P516= (on ENST00000449561 / NM_001081442.3; = p.P515= on NM_006840.5) | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as COSV100300928; called by muse, mutect2, varscan2
- LMAN1L | c.306G>A p.L102= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs1167897043, COSV100547871; called by muse, mutect2, varscan2
- LRCH3 | c.1986G>A p.L662= | Silent (SNP) | VAF 12/212 reads (6%) | catalogued as COSV100605310; called by muse, mutect2
- LRP2 | c.12169C>T p.L4057= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as COSV99790750; called by muse, mutect2
- LTBP3 | c.1227G>A p.V409= | Silent (SNP) | VAF 16/235 reads (7%) | catalogued as COSV100100533; called by muse, mutect2
- MAGI1 | c.3450G>A p.L1150= (on ENST00000402939 / NM_001033057.2; = p.L1179= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/1270 reads (3%) | catalogued as COSV100443458; called by muse, mutect2
- MAML1 | c.1671G>A p.L557= | Silent (SNP) | VAF 19/152 reads (13%) | catalogued as COSV99483534; called by muse, mutect2, varscan2
- MARCHF4 | c.1221C>T p.V407= | Silent (SNP) | VAF 27/363 reads (7%) | catalogued as COSV99814910; called by muse, mutect2
- MARF1 | c.4611G>A p.L1537= | Silent (SNP) | VAF 30/562 reads (5%) | called by muse, mutect2
- MEI1 | c.2670G>A p.L890= | Silent (SNP) | VAF 16/432 reads (4%) | catalogued as COSV100300489; called by muse, mutect2
- MFSD11 | c.375C>T p.I125= | Silent (SNP) | VAF 11/135 reads (8%) | catalogued as COSV100333548, COSV100334361; called by muse, mutect2
- MFSD13A | c.87G>A p.L29= | Silent (SNP) | VAF 16/320 reads (5%) | catalogued as COSV99488116; called by muse, mutect2
- MGLL | c.207C>T p.D69= (on ENST00000398104 / NM_001003794.2; = p.D79= on NM_007283.6) | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV99412480; called by muse, mutect2
- MXRA5 | c.1171C>T p.L391= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- MYCBP2 | c.1086C>T p.Y362= (on ENST00000357337; = p.Y400= on NM_015057.5) | Silent (SNP) | VAF 10/227 reads (4%) | catalogued as rs1199799809, COSV100632407; called by muse, mutect2
- NEURL1 | c.525G>A p.K175= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100872846; called by muse, mutect2
- NFX1 | c.774C>A p.G258= | Silent (SNP) | VAF 26/518 reads (5%) | catalogued as COSV100582548; called by muse, mutect2
- NGFR | c.1041G>A p.V347= | Silent (SNP) | VAF 52/379 reads (14%) | catalogued as COSV99413115; called by muse, mutect2, varscan2
- NHS | c.1962C>A p.A654= | Silent (SNP) | VAF 29/649 reads (4%) | catalogued as COSV101197083; called by muse, mutect2
- NLGN1 | c.144G>A p.L48= | Silent (SNP) | VAF 14/385 reads (4%) | called by muse, mutect2
- NLRP13 | c.1380C>T p.F460= | Silent (SNP) | VAF 1286/2041 reads (63%) | catalogued as COSV100738433, COSV99048651; called by mutect2, varscan2
- NLRP5 | c.1957C>T p.L653= | Silent (SNP) | VAF 6/74 reads (8%) | catalogued as COSV101173974, COSV101174004; called by muse, mutect2
- NTNG1 | c.1005C>A p.G335= | Silent (SNP) | VAF 36/453 reads (8%) | catalogued as COSV99640137; called by muse, mutect2
- OBSCN | c.2871C>T p.A957= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as rs541821422, COSV99485908; called by muse, mutect2, varscan2
- OLFML2A | c.1596C>T p.V532= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV56582742; called by muse, varscan2
- OR2D2 | c.546T>A p.P182= | Silent (SNP) | VAF 14/221 reads (6%) | called by muse, mutect2
- OR2S2 | c.846C>A p.P282= | Silent (SNP) | VAF 9/123 reads (7%) | catalogued as COSV100558740, COSV59529206; called by muse, mutect2
- OR51I2 | c.192C>T p.S64= | Silent (SNP) | VAF 61/478 reads (13%) | catalogued as COSV100413393, COSV100413508; called by muse, mutect2, varscan2
- OR51I2 | c.615C>T p.S205= | Silent (SNP) | VAF 32/646 reads (5%) | catalogued as rs1445472247, COSV100413509; called by muse, mutect2
- OR5H6 | c.39C>T p.C13= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as COSV101051829; called by muse, mutect2
- PDE5A | c.1554G>A p.K518= | Silent (SNP) | VAF 24/430 reads (6%) | catalogued as COSV99309369; called by muse, mutect2
- PIK3R4 | c.2871T>C p.A957= | Silent (SNP) | VAF 25/502 reads (5%) | catalogued as COSV100768647; called by muse, mutect2
- POC1A | c.1203C>T p.I401= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as COSV99624027, COSV99624700; called by muse, mutect2, varscan2
- PRPF8 | c.3801C>T p.L1267= | Silent (SNP) | VAF 9/130 reads (7%) | catalogued as rs529266484; called by muse, mutect2
- PTCD2 | c.328C>T p.L110= | Silent (SNP) | VAF 27/912 reads (3%) | catalogued as COSV100349211; called by muse, mutect2
- PTPRJ | c.3741C>T p.G1247= | Silent (SNP) | VAF 16/398 reads (4%) | catalogued as COSV101395824; called by muse, mutect2
- PXDC1 | c.279C>T p.A93= | Silent (SNP) | VAF 8/126 reads (6%) | catalogued as COSV100977220; called by muse, mutect2
- RBM19 | c.1803C>T p.A601= | Silent (SNP) | VAF 34/438 reads (8%) | catalogued as rs140359157, COSV55689530; called by muse, mutect2
- RBPMS2 | c.378G>A p.V126= | Silent (SNP) | VAF 19/128 reads (15%) | catalogued as COSV100265018; called by muse, mutect2, varscan2
- REV3L | c.3768A>T p.G1256= | Silent (SNP) | VAF 22/203 reads (11%) | catalogued as COSV100725761; called by muse, mutect2, varscan2
- RHOBTB1 | c.822C>T p.D274= | Silent (SNP) | VAF 12/300 reads (4%) | catalogued as COSV100558752; called by muse, mutect2
- RIC8B | c.1104C>T p.S368= | Silent (SNP) | VAF 16/361 reads (4%) | catalogued as rs1391158768, COSV100822755; called by muse, mutect2
- RLF | c.1392T>C p.P464= | Silent (SNP) | VAF 16/256 reads (6%) | catalogued as COSV101035785; called by muse, mutect2
- RNASET2 | c.606C>T p.C202= | Silent (SNP) | VAF 36/502 reads (7%) | catalogued as COSV99218710; called by muse, mutect2
- RORC | c.1266C>T p.A422= | Silent (SNP) | VAF 34/263 reads (13%) | catalogued as rs1426651842, COSV59092206; called by muse, mutect2, varscan2
- RRM1 | c.237C>T p.A79= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs769263947, COSV100331504; called by muse, mutect2, varscan2
- RUVBL1 | c.1272C>T p.S424= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV59476491; called by muse, mutect2, varscan2
- SELP | c.618T>A p.P206= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as COSV99741364; called by muse, mutect2
- SHPK | c.600C>T p.A200= | Silent (SNP) | VAF 20/428 reads (5%) | catalogued as COSV99844068; called by muse, mutect2
- SLC24A4 | c.1672C>T p.L558= | Silent (SNP) | VAF 28/242 reads (12%) | catalogued as COSV100106458; called by muse, mutect2, varscan2
- SLC39A7 | c.909T>A p.P303= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- SLMAP | c.1809G>A p.L603= (on ENST00000428312 / NM_001377924.1; = p.L665= on NM_007159.5) | Silent (SNP) | VAF 17/181 reads (9%) | catalogued as COSV99909415; called by muse, mutect2, varscan2
- SMAD3 | c.504A>G p.A168= | Silent (SNP) | VAF 29/261 reads (11%) | catalogued as COSV100529664; called by muse, mutect2, varscan2
- SPATA32 | c.465G>A p.K155= | Silent (SNP) | VAF 14/182 reads (8%) | catalogued as COSV100077645; called by muse, mutect2
- ST6GALNAC1 | c.1140C>G p.G380= | Silent (SNP) | VAF 9/146 reads (6%) | called by muse, mutect2
- SYMPK | c.2836C>T p.L946= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV99842255; called by muse, mutect2, varscan2
- TAF1L | c.2670A>G p.P890= | Silent (SNP) | VAF 18/575 reads (3%) | called by muse, mutect2
- TEX15 | c.474A>G p.P158= (on ENST00000256246; = p.P541= on NM_001350162.2) | Silent (SNP) | VAF 22/222 reads (10%) | catalogued as rs764432378, COSV99822356; called by muse, mutect2
- TG | c.7480A>C p.R2494= | Silent (SNP) | VAF 17/330 reads (5%) | catalogued as COSV99603879; called by muse, mutect2
- THRA | c.729T>A p.P243= | Silent (SNP) | VAF 48/924 reads (5%) | catalogued as COSV99225861; called by muse, mutect2
- TIMELESS | c.3027C>T p.S1009= | Silent (SNP) | VAF 37/982 reads (4%) | catalogued as COSV99974455; called by muse, mutect2
- TMTC1 | c.2442G>A p.V814= (on ENST00000539277 / NM_001193451.2; = p.V706= on NM_175861.3) | Silent (SNP) | VAF 25/280 reads (9%) | catalogued as rs1439446836, COSV55488098, COSV99761450; called by muse, mutect2
- TNC | c.6132T>C p.A2044= | Silent (SNP) | VAF 13/225 reads (6%) | catalogued as COSV100406451; called by muse, mutect2
- TPX2 | c.2214T>C p.S738= | Silent (SNP) | VAF 47/899 reads (5%) | catalogued as COSV100302187; called by muse, mutect2
- TRIM52 | c.318C>A p.L106= | Silent (SNP) | VAF 20/422 reads (5%) | catalogued as COSV100580795; called by muse, mutect2
- TRRAP | c.9378A>G p.G3126= (on ENST00000359863 / NM_001244580.1; = p.G3097= on NM_003496.3) | Silent (SNP) | VAF 28/348 reads (8%) | catalogued as COSV100723207; called by muse, mutect2
- TTC39A | c.162C>T p.S54= | Silent (SNP) | VAF 33/946 reads (3%) | catalogued as COSV99397218; called by muse, mutect2
- TTN | c.43119G>A p.L14373= (on ENST00000591111; = p.L6949= on NM_003319.4) | Silent (SNP) | VAF 16/187 reads (9%) | catalogued as COSV100635067; called by muse, mutect2
- TTYH1 | c.990G>T p.L330= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as COSV100002514; called by muse, mutect2
- TUBA4A | c.924G>A p.R308= | Silent (SNP) | VAF 34/448 reads (8%) | catalogued as COSV50278064; called by muse, mutect2
- TUSC3 | c.612G>A p.L204= | Silent (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- VPS13B | c.5475G>A p.Q1825= | Silent (SNP) | VAF 10/145 reads (7%) | catalogued as COSV100664011; called by muse, mutect2
- WASHC3 | c.411C>T p.A137= | Silent (SNP) | VAF 14/425 reads (3%) | catalogued as COSV99527682; called by muse, mutect2
- WDFY3 | c.2748C>T p.D916= | Silent (SNP) | VAF 21/167 reads (13%) | catalogued as COSV99886269; called by muse, mutect2, varscan2
- WDR62 | c.630C>T p.S210= | Silent (SNP) | VAF 25/207 reads (12%) | catalogued as COSV99544395; called by muse, mutect2, varscan2
- WIZ | c.4803C>T p.R1601= (on ENST00000673675 / NM_001371589.1; = p.R506= on NM_021241.3) | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as rs1369801295, COSV99653948; called by muse, mutect2, varscan2
- ZMYM5 | c.222A>T p.P74= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as COSV100562882; called by muse, mutect2
- ZNF148 | c.2085C>T p.N695= | Silent (SNP) | VAF 6101/6295 reads (97%) | catalogued as COSV62305842; called by muse, mutect2, varscan2
- ZNF776 | c.228A>T p.P76= | Silent (SNP) | VAF 14/283 reads (5%) | catalogued as COSV100414371; called by muse, mutect2
- AL109984.1 | n.186+4852G>A | Intron (SNP) | VAF 39/232 reads (17%) | catalogued as rs140282228; called by muse, mutect2, varscan2
- AL109984.1 | n.186+5059C>G | Intron (SNP) | VAF 34/209 reads (16%) | catalogued as COSV100802263; called by muse, mutect2, varscan2
- CLCN5 | c.17-33345C>T | Intron (SNP) | VAF 6/102 reads (6%) | catalogued as COSV101067374; called by muse, mutect2
- COPS9 | chr2:240126804 C>T | 3'Flank (SNP) | VAF 29/238 reads (12%) | catalogued as rs754723881, COSV100217185; called by muse, mutect2, varscan2
- CSNK1G2 | c.-266+12036G>A | Intron (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99730323; called by muse, mutect2
- ERAL1 | chr17:28861438 A>G | 3'Flank (SNP) | VAF 13/103 reads (13%) | called by muse, mutect2, varscan2
- MTRNR2L6 | chr7:142671105 T>C | 3'Flank (SNP) | VAF 20/586 reads (3%) | called by muse, mutect2
- NBPF7 | n.497G>A | RNA (SNP) | VAF 24/390 reads (6%) | called by muse, mutect2
- TRIB2 | c.563+1192C>T | Intron (SNP) | VAF 20/552 reads (4%) | called by muse, mutect2
- TRPM3 | c.184-256699G>A | Intron (SNP) | VAF 16/486 reads (3%) | catalogued as COSV100623876; called by muse, mutect2
- VNN3 | c.*39T>A | 3'UTR (SNP) | VAF 18/464 reads (4%) | called by muse, mutect2
- ZNF211 | c.90+590C>T | Intron (SNP) | VAF 20/260 reads (8%) | catalogued as COSV99560570; called by muse, mutect2
